Somatic mutation profile of tumor specimen MP2PRT-PARBIA-TMP1-A (aliquot MP2PRT-PARBIA-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARBIA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,135 days).
Specimen MP2PRT-PARBIA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc9e7d41-5c31-46f3-88b1-841c00e82132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARBIA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARBIA-NM1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5850798-5f28-459e-aadb-6cf52952817a

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 37/248 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 37/252 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANK3 | c.6896C>A p.A2299E | Missense Mutation (SNP) | VAF 32/591 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV55062984; called by muse, mutect2
- CTNND2 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 48/950 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs760066114, COSV58861744; called by muse, mutect2
- EEF1A2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 45/780 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1448765509, COSV53205645; called by muse, mutect2
- EHBP1L1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 44/725 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs902837840, COSV58573937; called by muse, mutect2
- KIF5C | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 62/520 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs1402890982, COSV68479619; called by muse, mutect2, varscan2
- LRFN1 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 235/642 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1254139255, COSV50442832; called by muse, mutect2, varscan2
- MYH13 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs146716231; called by muse, mutect2, varscan2
- SLC35F4 | c.707G>A p.R236Q (on ENST00000339762 / NM_001352015.2; = p.R200Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as rs373752532; called by muse, varscan2
- STYXL2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 46/685 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759090442, COSV54802091; called by muse, mutect2
- TMEM132B | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 38/622 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs781241046, COSV54769432; called by muse, mutect2
- USP2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 231/859 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs753856549; called by muse, mutect2, varscan2
- UTP4 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 38/618 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs770418250, COSV100077147; called by muse, mutect2
- ZIC4 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 106/746 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV101268046; called by muse, mutect2, varscan2
- AJM1 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 238/608 reads (39%) | called by muse, mutect2, varscan2
- DENND2B | c.1835G>C p.R612P | Missense Mutation (SNP) | VAF 131/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EPB41L1 | c.1612C>A p.L538M | Missense Mutation (SNP) | VAF 36/463 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- EPS8 | c.2015G>T p.S672I | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FAM122A | c.95_114del p.L32Pfs*8 | Frame Shift Del (DEL) | VAF 225/800 reads (28%) | called by mutect2, pindel, varscan2
- GRIA2 | c.2389G>A p.G797R | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2
- PTPRN | c.2858T>G p.V953G | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR45B | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 88/966 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.441); called by muse, mutect2
- CD163L1 | c.162C>T p.D54= | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as rs770900910; called by muse, mutect2
- OR5M8 | c.111G>A p.T37= | Silent (SNP) | VAF 54/736 reads (7%) | catalogued as rs376992051; called by muse, mutect2
- ZNF536 | c.1698C>T p.Y566= | Silent (SNP) | VAF 63/410 reads (15%) | catalogued as rs547191428; called by muse, mutect2, varscan2
